Gene-level copy-number profile of specimen HCM-CSHL-0369-D37-85P from HCMI case HCM-CSHL-0369-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 62.2 years (22,734 days).
Specimen HCM-CSHL-0369-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 75ce2422-26ac-48ad-99fa-c09ef665f3c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0369-D37-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/6778a2fb-ddd8-434d-9280-2b3643490605

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 478; copy number 1: 150; copy number 2: 54,315; copy number 3: 3,425; copy number 4: 4; copy number 5: 2; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 478 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:38,628,005–39,180,499, 1 gene (within-gene range 0–2): LINC02694.
- chr15:38,865,322–56,918,571, 474 genes (within-gene range 0–2) (broad region; genes not listed).
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–2): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:11,351,823–11,395,566, 1 gene, copy number 6 (within-gene range 3–6): PRB1.
- chr21:8,603,547–8,680,934, 2 genes, copy number 5: RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
